Somatic mutation profile of tumor specimen ALCH-ADTC-TTP1-A (aliquot ALCH-ADTC-TTP1-A-1-0-D-A582-36) from ALCHEMIST case ALCH-ADTC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.4 years (20,955 days).
Specimen ALCH-ADTC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e5ae9c7-9c66-42df-886d-1bfa87d3168c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADTC-NB1-A (Blood Derived Normal), aliquot ALCH-ADTC-NB1-A-1-0-D-A582-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78f20a68-f7ce-430d-bbb4-fa07a76981dc

The open-access MAF lists 50 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 11, Intron 3, 5'UTR 2, Nonsense Mutation 2, Splice Site 2, 3'UTR 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 201/684 reads (29%) | hotspot (GDC flag); catalogued as rs137854580, CM930023, COSV57322064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 204/1074 reads (19%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- LMNA | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 96/349 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397517889, CM025348, COSV61542211; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3460G>A p.A1154T (on ENST00000404938 / NM_001163941.2; = p.A709T on NM_178559.6) | Missense Mutation (SNP) | VAF 60/271 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51716288; called by muse, mutect2, varscan2
- CD79A | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 110/420 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as rs143511203; ClinVar: not provided; called by muse, mutect2, varscan2
- HPD | c.351C>G p.I117M | Missense Mutation (SNP) | VAF 150/446 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.852); catalogued as COSV56643523; called by mutect2, varscan2
- IGHJ4 | c.3C>G p.Y1* | Nonsense Mutation (SNP) | VAF 115/419 reads (27%) | catalogued as rs368028316; called by muse, mutect2, varscan2
- LOXHD1 | c.2318G>A p.R773H | Missense Mutation (SNP) | VAF 142/355 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs550645601; called by muse, mutect2, varscan2
- SLC22A24 | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs770233577, COSV100400065; called by muse, mutect2, varscan2
- SRPRB | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 105/334 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs141286101; called by muse, mutect2, varscan2
- TMOD1 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 74/326 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs369490245; called by muse, mutect2, varscan2
- USP6NL | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 95/413 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs376379995; called by muse, mutect2, varscan2
- ATG2B | c.2643A>T p.E881D | Missense Mutation (SNP) | VAF 18/536 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- ATP1B2 | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 106/264 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- COL12A1 | c.8539G>C p.D2847H | Missense Mutation (SNP) | VAF 50/358 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM120A | c.721+3_721+6del p.X241_splice | Splice Site (DEL) | VAF 46/228 reads (20%) | called by pindel, varscan2
- GZMH | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 82/332 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, varscan2
- HPD | c.186C>G p.I62M | Missense Mutation (SNP) | VAF 280/495 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- ITGAX | c.2798A>G p.Q933R | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MTDH | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 120/694 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCSK9 | c.2063C>G p.S688C | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- PLEK | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 98/340 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- PPL | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 117/292 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- RIPOR1 | c.1897C>T p.P633S (on ENST00000379312 / NM_001193522.2; = p.P629S on NM_024519.4) | Missense Mutation (SNP) | VAF 73/242 reads (30%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPS24 | c.69+1G>A p.X23_splice | Splice Site (SNP) | VAF 290/1189 reads (24%) | called by muse, mutect2, varscan2
- RREB1 | c.3183G>T p.E1061D | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SETD1B | c.2932C>G p.Q978E | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- TFEC | c.242A>T p.D81V | Missense Mutation (SNP) | VAF 116/512 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- TSNARE1 | c.312C>G p.D104E | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TTN | c.14295G>C p.E4765D (on ENST00000591111; = p.E3838D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | PolyPhen possibly damaging (0.496); called by muse, mutect2
- USP6NL | c.2444G>C p.R815T | Missense Mutation (SNP) | VAF 66/286 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); called by muse, mutect2
- WASHC5 | c.3331A>G p.T1111A | Missense Mutation (SNP) | VAF 216/897 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AKAP1 | c.1281G>A p.E427= | Silent (SNP) | VAF 68/328 reads (21%) | called by muse, mutect2, varscan2
- ATP1B2 | c.339C>T p.F113= | Silent (SNP) | VAF 100/295 reads (34%) | called by muse, mutect2, varscan2
- CNOT6 | c.1518G>A p.L506= | Silent (SNP) | VAF 57/1167 reads (5%) | called by muse, mutect2
- GABRA5 | c.903G>A p.T301= | Silent (SNP) | VAF 58/205 reads (28%) | catalogued as rs866302895, COSV59486600; called by muse, mutect2, varscan2
- GZMH | c.327C>T p.I109= | Silent (SNP) | VAF 75/304 reads (25%) | called by muse, varscan2
- HPD | c.69C>G p.T23= | Silent (SNP) | VAF 449/830 reads (54%) | catalogued as COSV100000261; called by muse, varscan2
- JAK3 | c.3106C>A p.R1036= | Silent (SNP) | VAF 43/179 reads (24%) | catalogued as COSV99070365; called by muse, mutect2, varscan2
- KIR2DL1 | c.324C>A p.P108= | Silent (SNP) | VAF 9/212 reads (4%) | called by muse, mutect2
- MYO5B | c.315C>T p.I105= | Silent (SNP) | VAF 42/738 reads (6%) | catalogued as rs748097712, COSV53215610, COSV53227808; called by muse, mutect2
- PDLIM4 | c.924G>A p.A308= | Silent (SNP) | VAF 37/389 reads (10%) | catalogued as rs1140552; called by muse, mutect2
- PRDM7 | c.1478G>A p.*493= | Silent (SNP) | VAF 202/929 reads (22%) | called by muse, mutect2, varscan2
- ARHGEF7 | c.823-2597G>C | Intron (SNP) | VAF 105/498 reads (21%) | called by muse, mutect2, varscan2
- CHRD | c.1065+22G>T | Intron (SNP) | VAF 94/353 reads (27%) | called by muse, mutect2, varscan2
- FH | c.*33A>G | 3'UTR (SNP) | VAF 107/495 reads (22%) | catalogued as rs1308542015; called by muse, mutect2, varscan2
- MORN1 | c.538-4603C>T | Intron (SNP) | VAF 104/450 reads (23%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.3343T>C | RNA (SNP) | VAF 108/389 reads (28%) | called by muse, mutect2, varscan2
- SERINC2 | c.-28C>T | 5'UTR (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- TDO2 | c.-13G>A | 5'UTR (SNP) | VAF 94/471 reads (20%) | called by muse, mutect2, varscan2
